Somatic mutation profile of tumor specimen MMRF_1565_1_BM_CD138pos (aliquot MMRF_1565_1_BM_CD138pos_T1_KBS5U_L05545) from MMRF case MMRF_1565, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 39.2 years (14,330 days).
Specimen MMRF_1565_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a3b04d3-8d49-4910-99ed-a721c3517b15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1565_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1565_1_PB_Whole_C3_KBS5U_L05566; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d677e560-2259-4733-a386-116cb77704e3

The open-access MAF lists 60 somatic variants for this specimen: 33 protein-altering or splice-affecting, 5 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 13, Silent 5, Intron 4, 5'UTR 3, Frame Shift Del 2, Splice Region 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2338A>G p.R780G | Missense Mutation (SNP) | VAF 6/148 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66708015; called by muse, mutect2
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 33/75 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTG2 | c.386A>G p.N129S | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.04); catalogued as rs774695960; called by muse, mutect2, varscan2
- CTR9 | c.2138A>G p.K713R | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs776826008; called by muse, mutect2, varscan2
- DIS3 | c.2072A>G p.H691R | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1463844162; called by muse, mutect2, varscan2
- GSTA3 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as rs141510758; called by muse, mutect2, varscan2
- H1-3 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.054); catalogued as rs373384671; called by muse, mutect2, varscan2
- KIAA1217 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 118/284 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV64608955; called by muse, mutect2, varscan2
- LRP1B | c.7315A>G p.T2439A | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.708); catalogued as rs761694211; called by muse, varscan2
- LRRC3B | c.601del p.T201Lfs*17 | Frame Shift Del (DEL) | VAF 47/125 reads (38%) | catalogued as COSV67521526; called by mutect2, pindel, varscan2
- MEN1 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV53645607; called by muse, varscan2
- MPDZ | c.2039C>T p.A680V | Missense Mutation (SNP) | VAF 172/291 reads (59%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs370396750; called by muse, mutect2, varscan2
- MUC2 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.46); catalogued as rs751277029; called by muse, mutect2, varscan2
- SHANK2 | c.1738G>A p.V580M | Missense Mutation (SNP) | VAF 83/277 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs781792116, COSV99573525; called by muse, mutect2, varscan2
- SLC11A1 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as rs1466824924; called by muse, mutect2, varscan2
- SLC12A4 | c.3103G>A p.D1035N | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs761143750, COSV99863050; called by muse, mutect2, varscan2
- SPTB | c.5236C>T p.R1746W | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200080131; called by muse, mutect2, varscan2
- ACTR8 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ATP7A | c.712G>C p.V238L | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP47 | c.4742T>A p.F1581Y | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FSIP2 | c.10490A>C p.Q3497P | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNAL | c.382G>C p.E128Q (on ENST00000269162 / NM_001142339.3; = p.E205Q on NM_182978.4) | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- IGHV1-45 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT tolerated (0.57); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- LAMC1 | c.3567T>G p.R1189= | Splice Region (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- LRP1B | c.7240T>C p.Y2414H | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, varscan2
- LRRN3 | c.1106C>A p.P369H | Missense Mutation (SNP) | VAF 83/312 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH2 | c.2079G>C p.E693D | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- PCDH17 | c.36G>T p.W12C | Missense Mutation (SNP) | VAF 86/231 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- RP1L1 | c.4606A>G p.S1536G | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- TRIO | c.893G>A p.G298D | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.051); called by muse, mutect2
- ZCCHC8 | c.692A>C p.N231T | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZCCHC8 | c.483del p.N161Kfs*9 | Frame Shift Del (DEL) | VAF 72/216 reads (33%) | called by pindel, varscan2
- ZNF286A | c.378A>T p.Q126H | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- BID | c.489C>T p.S163= (on ENST00000317361 / NM_197966.2; = p.S117= on NM_001196.4) | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as rs1374860608; called by muse, mutect2
- CSMD2 | c.891C>T p.R297= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs143306375; called by muse, mutect2, varscan2
- MEGF10 | c.1920C>T p.H640= | Silent (SNP) | VAF 82/147 reads (56%) | catalogued as rs1242291278; called by muse, mutect2, varscan2
- MREG | c.279T>C p.D93= | Silent (SNP) | VAF 41/93 reads (44%) | called by muse, mutect2, varscan2
- NR3C2 | c.2925C>T p.N975= | Silent (SNP) | VAF 137/266 reads (52%) | catalogued as rs1048114231; called by muse, mutect2, varscan2
- ACAT1 | c.435+1539G>C | Intron (SNP) | VAF 94/285 reads (33%) | called by muse, mutect2, varscan2
- ATF4 | c.-88_-52del | 5'UTR (DEL) | VAF 14/53 reads (26%) | called by mutect2, pindel
- CHN1 | c.550-796T>G | Intron (SNP) | VAF 48/113 reads (42%) | catalogued as COSV55036257; called by muse, mutect2, varscan2
- CPPED1 | c.*864G>A | 3'UTR (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- CREB1 | c.*5176A>G | 3'UTR (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- ERBB3 | c.*172G>A | 3'UTR (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- EXOC5 | c.*146C>T | 3'UTR (SNP) | VAF 150/360 reads (42%) | called by muse, mutect2
- FNIP2 | c.*13G>A | 3'UTR (SNP) | VAF 32/217 reads (15%) | called by muse, mutect2, varscan2
- KLHDC4 | c.1044+29G>A | Intron (SNP) | VAF 16/130 reads (12%) | catalogued as rs765200655, COSV54511316; called by muse, mutect2, varscan2
- MARCHF8 | c.*2995T>G | 3'UTR (SNP) | VAF 51/141 reads (36%) | called by muse, mutect2, varscan2
- NAV3 | c.*1742G>C | 3'UTR (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- NLGN4X | c.*822A>T | 3'UTR (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- PELI2 | c.*2453del | 3'UTR (DEL) | VAF 36/62 reads (58%) | catalogued as rs1003755244; called by mutect2, varscan2
- PRRX1 | c.*2193C>A | 3'UTR (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- PTEN | c.-726C>T | 5'UTR (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- RIN3 | c.-4C>T | 5'UTR (SNP) | VAF 3/22 reads (14%) | catalogued as rs1300942704; called by muse, mutect2
- RTKN2 | c.*3642T>A | 3'UTR (SNP) | VAF 57/203 reads (28%) | called by muse, mutect2, varscan2
- SFRP1 | c.*1964G>C | 3'UTR (SNP) | VAF 4/83 reads (5%) | called by muse, mutect2
- SLIT1 | c.1086-806C>G | Intron (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- TARDBPP2 | n.953C>G | RNA (SNP) | VAF 46/90 reads (51%) | called by muse, mutect2, varscan2
- TKFC | c.*604C>G | 3'UTR (SNP) | VAF 39/104 reads (38%) | called by muse, mutect2, varscan2
- WWC2 | chr4:183098914 C>T | 5'Flank (SNP) | VAF 49/110 reads (45%) | called by muse, mutect2, varscan2
